Somatic mutation profile of tumor specimen ALCH-B3EM-TTP1-A (aliquot ALCH-B3EM-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3EM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.5 years (27,572 days).
Specimen ALCH-B3EM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3ef4e79-e764-4b13-8c36-15c96de4f6ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3EM-NB1-A (Blood Derived Normal), aliquot ALCH-B3EM-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1ad286b-01f0-4ae6-9c3c-3c6eed357b85

The open-access MAF lists 243 somatic variants for this specimen: 156 protein-altering or splice-affecting, 56 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 56, Intron 21, 5'UTR 5, Nonsense Mutation 5, RNA 3, Splice Site 2, 3'UTR 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, varscan2
- POLH | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 30/484 reads (6%) | catalogued as rs759607901, CM141001; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 43/317 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4162C>A p.Q1388K | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as rs376711746; called by muse, mutect2, varscan2
- ADCY10 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375709824, COSV100896660; called by muse, mutect2
- ADGRA1 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as COSV101658594; called by muse, mutect2, varscan2
- ADNP | c.3010G>C p.E1004Q | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.301); catalogued as rs759208073; called by muse, mutect2, varscan2
- ANKRD30A | c.2537T>C p.L846P (on ENST00000611781; = p.L790P on NM_052997.2) | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.965); catalogued as rs779502544, COSV64604040; called by muse, mutect2, varscan2
- ANKRD6 | c.1702T>A p.S568T (on ENST00000339746 / NM_001242809.2; = p.S563T on NM_014942.4) | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1328658607; called by muse, mutect2
- ATP11C | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59575243; called by muse, mutect2, varscan2
- ATXN7L1 | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs562318903; called by muse, mutect2
- CACNA1H | c.6860G>A p.S2287N | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs751085066; called by muse, mutect2, varscan2
- CYP21A2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs770379536, CM110263; called by muse, mutect2
- ERBB4 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs367568427, COSV61471739, COSV99048406; called by muse, mutect2
- F8 | c.6379G>A p.D2127N | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as CD020232; called by muse, mutect2, varscan2
- FAM135B | c.2186A>C p.E729A | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs896052944; called by muse, mutect2
- GCG | c.536G>T p.R179M | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs1410998244; called by muse, mutect2
- GINM1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1183286450; called by muse, mutect2
- GMEB1 | c.840A>G p.I280M | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV53796274; called by muse, mutect2
- HEPH | c.2163C>A p.H721Q (on ENST00000343002; = p.H454Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100295120; called by muse, mutect2
- KCTD13 | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1464351006; called by muse, mutect2, varscan2
- KIF3C | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs148571793; called by muse, mutect2
- KLB | c.2301C>A p.F767L | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1171126878; called by muse, mutect2, varscan2
- KRT12 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.313); catalogued as rs765897573, COSV52431070; called by muse, mutect2
- KRT31 | c.1142C>G p.P381R | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV52435063; called by muse, mutect2, varscan2
- LRRC15 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV100752905; called by muse, mutect2, varscan2
- LZTS2 | c.1778G>T p.R593L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.018); catalogued as rs900315360, COSV99058736; called by muse, mutect2
- MAST3 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53224784; called by muse, mutect2
- MFHAS1 | c.3058G>A p.G1020S | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs202155225; called by muse, mutect2, varscan2
- MS4A1 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs557319997; called by muse, mutect2
- MUC4 | c.6289C>T p.L2097F | Missense Mutation (SNP) | VAF 82/420 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as rs1194349872, COSV100640228; called by muse, varscan2
- NEK9 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.259); catalogued as COSV53132322; called by muse, mutect2
- OR10C1 | c.218G>T p.G73V (on ENST00000622521; = p.G71V on NM_013941.3) | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs769481312; called by muse, mutect2, varscan2
- PFKFB1 | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 18/230 reads (8%) | PolyPhen probably damaging (0.998); catalogued as rs1454178195; called by muse, mutect2
- PLXNA1 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV52522159; called by muse, mutect2
- POLA2 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs1158684807, COSV55483903; called by muse, mutect2
- PRKDC | c.8917G>A p.D2973N | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1410525549; called by muse, mutect2, varscan2
- PROS1 | c.1916G>T p.C639F | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM051212, CM971249; called by muse, mutect2, varscan2
- PRR32 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV64420306, COSV64420675; called by muse, mutect2
- PTPRU | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867290552, COSV60534846; called by muse, mutect2
- RAPSN | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 33/322 reads (10%) | catalogued as CM094598, COSV100100314; called by muse, mutect2
- RIMS2 | c.1006G>A p.D336N (on ENST00000666250 / NM_001348490.2; = p.D144N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51709347; called by muse, mutect2, varscan2
- RYR1 | c.4402G>T p.V1468F | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62094433; called by muse, mutect2, varscan2
- SAMD9L | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as rs1403903644; called by muse, mutect2, varscan2
- SLC35F1 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV64504982; called by muse, mutect2, varscan2
- SLCO2A1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60488523; called by muse, mutect2
- SS18L1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 22/180 reads (12%) | catalogued as COSV59212270; called by muse, mutect2, varscan2
- STAG2 | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV54354295; called by muse, mutect2
- TEX2 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV51980815; called by muse, mutect2, varscan2
- TF | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.174); catalogued as rs367635811; called by muse, mutect2
- XIRP2 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774074321, COSV54710238, COSV99746745; called by muse, mutect2
- ZNF423 | c.1085G>A p.S362N (on ENST00000563137 / NM_001379286.1; = p.S354N on NM_015069.4) | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99284236; called by muse, mutect2, varscan2
- ZNF594 | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1465050492; called by muse, mutect2, varscan2
- ZNF683 | c.763C>G p.P255A | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62874266, COSV62875326; called by mutect2, varscan2
- AC138647.1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.275); called by muse, mutect2
- AC244197.3 | c.283T>A p.Y95N | Missense Mutation (SNP) | VAF 51/436 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADAM18 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2
- ADAM28 | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ADAMTSL1 | c.3016A>C p.S1006R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ARID1B | c.6404C>T p.A2135V | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- BFAR | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- C1orf68 | c.617G>T p.S206I | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CA8 | c.830C>G p.T277S | Missense Mutation (SNP) | VAF 63/588 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CAPRIN1 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- CC2D2A | c.2515T>C p.S839P | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CCDC168 | c.16025A>T p.E5342V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CCDC22 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CELF2 | c.170A>G p.K57R (on ENST00000416382 / NM_001025077.3; = p.K64R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- CEP162 | c.1616G>T p.S539I | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.246); called by muse, mutect2
- CFHR5 | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 50/525 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.314); called by muse, mutect2
- CLCNKB | c.2017-2A>T p.X673_splice | Splice Site (SNP) | VAF 20/160 reads (13%) | called by mutect2, varscan2
- CNTNAP4 | c.2032C>A p.Q678K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- DENND4C | c.2947G>A p.V983M (on ENST00000434457 / NM_001330640.2; = p.V934M on NM_017925.7) | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DISP1 | c.3864G>T p.Q1288H | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYNC1H1 | c.8234C>A p.T2745K | Missense Mutation (SNP) | VAF 27/390 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ELAPOR2 | c.1925A>C p.Y642S (on ENST00000450689 / NM_001142749.3; = p.Y475S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ENPP2 | c.2153G>T p.R718M (on ENST00000075322 / NM_001040092.3; = p.R770M on NM_006209.5) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- ENPP2 | c.1964C>T p.P655L (on ENST00000075322 / NM_001040092.3; = p.P707L on NM_006209.5) | Missense Mutation (SNP) | VAF 15/309 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2
- ENPP2 | c.1963C>A p.P655T (on ENST00000075322 / NM_001040092.3; = p.P707T on NM_006209.5) | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.066); called by muse, mutect2
- EPHB4 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB4 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ESF1 | c.1801A>T p.M601L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- FIGN | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- FTH1 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GC | c.1243_1255del p.F415Rfs*8 | Frame Shift Del (DEL) | VAF 13/140 reads (9%) | called by mutect2, pindel
- GCFC2 | c.1013A>C p.N338T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- GGH | c.755G>T p.W252L | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GIMAP8 | c.1043A>T p.Q348L | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- GLP2R | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GLT1D1 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2
- GRID2 | c.2134A>G p.I712V | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- HOPX | c.199G>T p.E67* (on ENST00000317745; = p.E85* on NM_032495.6) | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- ICAM5 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 17/267 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV1D-42 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ITIH6 | c.3859C>A p.P1287T | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- KIF26B | c.4577T>C p.V1526A | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIR3DL1 | c.502G>C p.V168L | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- KMT2B | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LDB1 | c.893A>C p.K298T (on ENST00000425280 / NM_001321612.2; = p.K262T on NM_003893.5) | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2
- LPXN | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.334); called by muse, mutect2
- LRFN2 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- MAGEB10 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.553); called by muse, mutect2
- MAMLD1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 29/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAP2K3 | c.596A>T p.N199I (on ENST00000342679 / NM_145109.3; = p.N170I on NM_002756.4) | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MAP7D2 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MATN4 | c.749A>C p.D250A | Missense Mutation (SNP) | VAF 13/126 reads (10%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MID2 | c.1468G>T p.V490F | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTERF1 | c.926A>T p.E309V | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MTMR8 | c.1330C>A p.Q444K | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- MUC22 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.19); called by muse, mutect2
- MYOCD | c.313G>C p.A105P | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NPAS1 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR4A15 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- OR4A16 | c.712T>A p.C238S | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR56A3 | c.623G>C p.W208S | Missense Mutation (SNP) | VAF 24/259 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- OR8K5 | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); called by muse, mutect2
- PAPPA | c.4606-2A>G p.X1536_splice | Splice Site (SNP) | VAF 14/201 reads (7%) | called by muse, mutect2
- PCDH11X | c.2083G>T p.V695F | Missense Mutation (SNP) | VAF 47/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PDE6B | c.279C>A p.S93R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIH1D2 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); called by muse, mutect2
- PLCB1 | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PNPLA5 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- PPP2R3A | c.2695C>T p.H899Y | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBM10 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RIMS2 | c.4439A>G p.Y1480C (on ENST00000666250 / NM_001348490.2; = p.Y1051C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPGR | c.2593G>A p.E865K (on ENST00000339363 / NM_001367249.1; = p.E660K on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- SAMD3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SBK2 | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- SELENBP1 | c.681C>G p.H227Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.009); called by muse, mutect2
- SERPINI1 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC23A2 | c.1923T>G p.S641R | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SMYD1 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORL1 | c.1501C>G p.P501A | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SORL1 | c.2758G>A p.V920M | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- SP100 | c.917A>T p.K306I | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2
- SP100 | c.918A>T p.K306N | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- SPP2 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2
- SS18L1 | c.543G>T p.M181I | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBXT | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 61/504 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TERT | c.3158G>T p.G1053V | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TEX13C | c.1589C>A p.P530Q | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- TNFSF13B | c.432A>T p.Q144H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TREM1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- TRIM51GP | c.1262G>T p.S421I | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TSC22D2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- TSEN34 | c.318G>T p.E106D | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TTC23L | c.327G>C p.W109C | Missense Mutation (SNP) | VAF 13/391 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNK | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- VSIG4 | c.189C>A p.D63E | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- WDFY4 | c.2422C>A p.Q808K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XIRP2 | c.1433C>A p.T478K (on ENST00000628543; = p.T653K on NM_152381.6) | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZBTB33 | c.461A>T p.D154V | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZFP62 | c.998G>A p.G333E (on ENST00000502412 / NM_001377944.1; = p.G300E on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF705G | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 30/692 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.084); called by muse, mutect2
- ZNF761 | c.659G>T p.S220I | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- AC138647.1 | c.60C>A p.A20= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- ADAM32 | c.1341C>T p.G447= | Silent (SNP) | VAF 18/217 reads (8%) | catalogued as rs570160976, COSV65948448; called by muse, mutect2
- ADGRA1 | c.36C>A p.S12= | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- ATP6AP2 | c.28T>C p.L10= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as rs1179524273; called by muse, mutect2, varscan2
- CCDC171 | c.927A>C p.R309= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- CNGA4 | c.177C>T p.P59= | Silent (SNP) | VAF 16/197 reads (8%) | catalogued as rs773492976, COSV56412341; called by muse, mutect2
- DDIT4L | c.135C>T p.N45= | Silent (SNP) | VAF 46/343 reads (13%) | catalogued as rs778259421; called by muse, mutect2, varscan2
- DNASE1L1 | c.804G>T p.V268= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- FASN | c.2196C>T p.A732= | Silent (SNP) | VAF 32/410 reads (8%) | catalogued as rs576390200, COSV60751350; called by muse, mutect2
- FBN1 | c.477G>A p.R159= | Silent (SNP) | VAF 16/399 reads (4%) | catalogued as rs1456579664; called by muse, mutect2
- FOXK1 | c.2079C>T p.S693= | Silent (SNP) | VAF 20/392 reads (5%) | catalogued as rs368673072; called by muse, mutect2
- GABRA4 | c.810A>G p.T270= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs916111984; called by muse, mutect2
- GABRB3 | c.915C>T p.A305= | Silent (SNP) | VAF 49/373 reads (13%) | called by muse, mutect2, varscan2
- GRM8 | c.1758G>T p.V586= | Silent (SNP) | VAF 16/257 reads (6%) | called by muse, mutect2
- HEPHL1 | c.2691T>C p.Y897= | Silent (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- INSRR | c.2238G>A p.R746= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs1233021526, COSV63877240; called by muse, mutect2, varscan2
- KCNK9 | c.1071G>T p.G357= | Silent (SNP) | VAF 77/489 reads (16%) | catalogued as rs1311345883; called by muse, mutect2, varscan2
- MEF2C | c.1284C>T p.S428= | Silent (SNP) | VAF 54/422 reads (13%) | called by mutect2, varscan2
- MSR1 | c.258T>C p.S86= | Silent (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- MTF1 | c.1251A>G p.L417= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- MTUS2 | c.843G>A p.E281= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.14982A>T p.S4994= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- MUC22 | c.4296C>T p.G1432= | Silent (SNP) | VAF 18/329 reads (5%) | called by muse, mutect2
- MUC4 | c.15729G>A p.P5243= (on ENST00000463781 / NM_018406.7; = p.P1007= on NM_004532.6) | Silent (SNP) | VAF 100/434 reads (23%) | catalogued as rs373244688; called by muse, mutect2, varscan2
- NAV2 | c.5538G>A p.K1846= (on ENST00000396087 / NM_001244963.2; = p.K1787= on NM_145117.5) | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1565019519; called by mutect2, varscan2
- NCF4 | c.537T>C p.F179= | Silent (SNP) | VAF 133/653 reads (20%) | called by muse, mutect2, varscan2
- NOSIP | c.873A>G p.Q291= | Silent (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- NOX5 | c.1221C>G p.L407= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- OR10AG1 | c.528C>T p.L176= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as rs1248005928; called by muse, mutect2
- OR10X1 | c.699T>A p.T233= | Silent (SNP) | VAF 33/311 reads (11%) | called by muse, mutect2, varscan2
- OR2B11 | c.525G>T p.R175= | Silent (SNP) | VAF 26/310 reads (8%) | called by muse, mutect2
- OR5H2 | c.129T>C p.T43= | Silent (SNP) | VAF 39/172 reads (23%) | catalogued as COSV100788623; called by muse, mutect2, varscan2
- OSMR | c.2703C>T p.Y901= | Silent (SNP) | VAF 15/386 reads (4%) | called by muse, mutect2
- PCDH11X | c.2082G>A p.V694= | Silent (SNP) | VAF 52/512 reads (10%) | catalogued as COSV53448581; called by muse, mutect2
- PCDHB9 | c.1635G>T p.A545= | Silent (SNP) | VAF 47/456 reads (10%) | catalogued as rs1417941624, COSV53380765; called by muse, mutect2, varscan2
- PHEX | c.2115C>A p.V705= | Silent (SNP) | VAF 33/435 reads (8%) | called by muse, mutect2
- PLEC | c.6027C>T p.D2009= (on ENST00000322810 / NM_201380.4; = p.D1899= on NM_000445.5) | Silent (SNP) | VAF 33/259 reads (13%) | catalogued as rs371589575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR36 | c.468C>G p.L156= | Silent (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- SLAMF1 | c.486G>C p.L162= | Silent (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- SLC6A11 | c.1848C>T p.L616= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- STAG3 | c.405C>T p.N135= | Silent (SNP) | VAF 36/300 reads (12%) | called by muse, mutect2, varscan2
- STIM1 | c.1266A>G p.A422= | Silent (SNP) | VAF 37/311 reads (12%) | called by muse, mutect2, varscan2
- STK36 | c.2898A>G p.Q966= | Silent (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- SYNE1 | c.8514T>C p.I2838= (on ENST00000367255 / NM_182961.4; = p.I2845= on NM_033071.3) | Silent (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- TAS2R8 | c.405G>A p.L135= | Silent (SNP) | VAF 30/234 reads (13%) | catalogued as rs1228297458; called by muse, mutect2, varscan2
- TENM1 | c.3588T>C p.A1196= | Silent (SNP) | VAF 50/435 reads (11%) | called by muse, mutect2, varscan2
- TPTE | c.1116G>A p.R372= (on ENST00000618007 / NM_199261.4; = p.R354= on NM_199259.4) | Silent (SNP) | VAF 20/700 reads (3%) | catalogued as rs1325288760; called by muse, mutect2
- TRIM28 | c.1494A>G p.T498= | Silent (SNP) | VAF 38/318 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.95361C>T p.Y31787= (on ENST00000591111; = p.Y24363= on NM_003319.4) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1440086089; called by muse, mutect2, varscan2
- UHRF1BP1 | c.189C>T p.C63= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV51957869; called by muse, mutect2, varscan2
- UNC79 | c.4872C>A p.L1624= (on ENST00000393151 / NM_001346218.2; = p.L1447= on NM_020818.5) | Silent (SNP) | VAF 13/237 reads (5%) | called by muse, mutect2
- WDFY4 | c.2421C>A p.P807= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- WDFY4 | c.3114A>G p.P1038= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- WWC3 | c.2979G>T p.L993= | Silent (SNP) | VAF 46/369 reads (12%) | called by muse, mutect2, varscan2
- XKR4 | c.1152C>A p.A384= | Silent (SNP) | VAF 32/275 reads (12%) | catalogued as rs551126259, COSV100530199; called by muse, mutect2, varscan2
- ZNF334 | c.1284A>G p.T428= | Silent (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- ABI3BP | c.1576+14086A>T | Intron (SNP) | VAF 35/255 reads (14%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83413T>C | Intron (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- ARSD | c.1000+844G>T | Intron (SNP) | VAF 37/216 reads (17%) | catalogued as COSV54199543; called by muse, mutect2, varscan2
- ATP2B2 | c.*287G>T | 3'UTR (SNP) | VAF 17/114 reads (15%) | catalogued as rs757823801, COSV59494186; called by muse, mutect2, varscan2
- C3orf33 | c.114+439C>G | Intron (SNP) | VAF 36/289 reads (12%) | called by muse, mutect2, varscan2
- CDK10 | c.87+751A>T | Intron (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- CYP2C8 | c.-43G>T | 5'UTR (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- DST | c.4296+4661C>A | Intron (SNP) | VAF 61/500 reads (12%) | called by muse, mutect2, varscan2
- ENDOV | c.838+36C>T | Intron (SNP) | VAF 7/171 reads (4%) | called by muse, mutect2
- EYA4 | c.1210-19G>A | Intron (SNP) | VAF 28/233 reads (12%) | catalogued as rs1193116821, COSV100765570; called by muse, mutect2, varscan2
- FN1 | c.6978+29A>C | Intron (SNP) | VAF 24/284 reads (8%) | called by muse, mutect2
- IQGAP2 | c.1358-1824C>G | Intron (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- LILRA2 | c.1255+1559T>C | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- LINC00303 | n.351C>T | RNA (SNP) | VAF 23/194 reads (12%) | catalogued as rs1221064296; called by muse, mutect2, varscan2
- MECP2 | c.-37A>T | 5'UTR (SNP) | VAF 71/513 reads (14%) | called by muse, mutect2, varscan2
- MYO1B | c.2470-35G>T | Intron (SNP) | VAF 19/185 reads (10%) | called by muse, mutect2, varscan2
- MYZAP | c.-55T>G | 5'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, varscan2
- NAALADL2 | c.1235-3260C>T | Intron (SNP) | VAF 36/269 reads (13%) | catalogued as rs747786738; called by muse, mutect2, varscan2
- NLRP2 | c.326-864C>T | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as rs1371300602; called by muse, mutect2, varscan2
- NRK | c.4354-832T>G | Intron (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2, varscan2
- NXF5 | n.287A>T | RNA (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- REEP1 | c.-11G>A | 5'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- SLC25A12 | c.1586-20A>C | Intron (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2, varscan2
- SLC30A3 | c.*211del | 3'UTR (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- TAZ | c.284+93G>A | Intron (SNP) | VAF 12/92 reads (13%) | catalogued as rs781794970; called by muse, mutect2, varscan2
- TNK2 | c.1543+562C>G | Intron (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2
- TUBE1 | c.152+892T>C | Intron (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- UBE3B | c.630+512G>C | Intron (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- XIST | n.7435T>A | RNA (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
- ZFYVE21 | c.190-143G>A | Intron (SNP) | VAF 8/161 reads (5%) | catalogued as rs1163313208; called by muse, mutect2
- ZNF233 | c.-18C>A | 5'UTR (SNP) | VAF 33/327 reads (10%) | called by muse, mutect2, varscan2
